Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A1G8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A1G8-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

100-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1

Case Number : -----

1/31/11
h

Diagnosis:

A: Uterus and cervix, hysterectomy and bilateral salpingo-oophorectomy:

Location of tumor: endometrium

Histologic type: endometrioid adenocarcinoma with spindle cell metaplasia

Histologic grade (FIGO): overall FIGO grade 3 (architectural grade 2, nuclear grade 3) (A3, A8) (see comment)

Extent of invasion:

Myometrial invasion: Inner half

Depth: 3 mm Wall thickness: 8 mm Percent: 37.5% (A3)

Serosal involvement: absent

Lower uterine segment involvement: Minute detached fragment of tumor focally noted in lower uterine segment; no stromal invasion identified.

Cervical involvement: absent

Adnexal involvement (see below): absent

Other sites:

Cervical/vaginal margin and distance: widely free

Lymphovascular Space Invasion: absent

Regional lymph nodes (see other specimens):

Total number involved: 0

Total number examined: 40

Other Pathologic findings:

- Atrophic endometrial polyp.
- Vascular calcifications noted within myometrium.

[page 2 of 5]
Hormone receptor status: ER positive (2-3+, 30%) and PR positive (2-3+, 30%), by immunohistochemistry (A3).

AJCC Pathologic stage: pT1b pN0 pMx

FIGO Stage grouping: IB

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right, oophorectomy:

- Atrophic ovary, no tumor seen.

Ovary, left, oophorectomy:

- Atrophic ovary, no tumor seen.

Fallopian tube, right, salpingectomy:

- Paratubal cyst, no tumor seen.

Fallopian tube, left, salpingectomy:

- No significant pathologic abnormality, no tumor seen.

B: Lymph node, peri-aortic, right, removal

- Nine lymph nodes, no tumor seen (0/9).

C: Lymph node, peri-aortic, left, removal

- Seven lymph nodes, no tumor seen (0/12).

D: Lymph node, pelvic, right, removal

- Eleven lymph nodes, no tumor seen (0/12).

E: Lymph node, pelvic, left, removal

- Seven lymph nodes, no tumor seen (0/7).

Comment:

Representative sections of tumor (A3 and A8) are shown in consultation to Dr. who also does not recognize evidence of carcinosarcoma, and concurs with the above diagnosis.

Clinical History:

with endometrial cancer. Outside biopsy was reviewed with diagnosis of well differentiated endometrioid adenocarcinoma, FIGO Grade 1. A robotic hysterectomy with BSO and lymph node dissection were performed.

Gross Description:

Received are five appropriately labeled containers.

[page 3 of 5]
Container A:

Adnexa: present bilaterally

Weight: 59.4 grams

Shape: pear shaped

Dimensions:

height: 6.7 cm

anterior to posterior width: 2.0 cm

breadth at fundus: 5.0 cm

Serosa: pink/tan and smooth

Cervix:

length of endocervical canal: 2.9 cm

ectocervix: pink/tan and smooth with hyperemia

endocervix: tan and trabeculated

Endomyometrium:

length of endometrial cavity: 3.6 cm

width of endometrial cavity at fundus: 1.7 cm

tumor findings:

dimensions: 2.5 x 2.0 x 0.6 cm

appearance: The mass is a multinodular, somewhat fungating, white/tan, soft mass.

location and extent: The mass appears to be in both the anterior and posterior corpus at the fundus, and appears to incorporate most of endometrium into the lower uterine segment particularly on the posterior aspect.

myometrial invasion: The inner one-half approximately, 0.2 cm.

thickness of myometrial wall at deepest gross invasion: 0.9 cm

other findings or comments: none

Adnexa:

Right ovary:

dimensions: 2.3 x 1.0 x 0.5 cm

external surface: pink/tan and vaguely lobulated

cut surface: yellow/tan and variegated

Right fallopian tube:

dimensions: 6.3 x 0.6 cm

other findings: none

Left ovary:

dimensions: 2.5 x 1.0 x 0.5 cm

external surface: yellow/tan and vaguely cerebriform

cut surface: yellow/tan and variegated

Left fallopian tube:

dimensions: 6.0 x 0.5 cm

[page 4 of 5]
other findings: none

Lymph nodes: assessed separately

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: Normal endometrium and cervix and tumor sent to Tissue Procurement.

Block Summary:

- A1 - anterior cervix
- A2 - anterior lower uterine segment
- A3 - anterior mid corpus
- A4 - anterior fundus
- A5 - posterior cervix
- A6 - posterior lower uterine segment
- A7 - posterior mid corpus
- A8 - posterior fundus
- A9 - right ovary and right fallopian tube
- A10 - left ovary and left fallopian tube

Container B is additionally labeled "right peri-aortic node." The specimen consists of a single yellow/tan fragment of fibroadipose tissue with a measurement of 5.2 x 2.5 x 0.7 cm. Four lymph node candidates are identified that measure between 0.8 and 2.5 cm.

Block Summary:

- B1 - three lymph node candidates
- B2 - one lymph node candidate, bisected
- B3,B4 - remaining fibroadipose tissue,

Container C is additionally labeled "left peri-aortic node." The specimen consists of a single yellow/tan fibroadipose tissue fragment that measures 4.8 x 2.8 x 1.2 cm. Five lymph node candidates are identified within tissue measuring between 0.4 up to 3.5 cm.

Block summary:

- C1 - four lymph node candidates
- C2 - one lymph node candidate, sectioned
- C3,C4 - remaining fibroadipose tissue,

Container D is additionally labeled "right pelvic lymph node." The specimen consists of multiple yellow/tan fibroadipose tissue fragments with an aggregate measurement of 4.0 x 4.2 x 1.8 cm. Eight lymph node candidates are identified within fibroadipose tissue ranging between 0.5 cm to 2.0 cm in diameter.

[page 5 of 5]
Block Summary:

- D1 - four lymph node candidates
- D2 - two lymph node candidates
- D3 - one lymph node candidate, bisected
- D4 - one lymph node candidate
- D5 - remaining fibroadipose tissue,

Container E is additionally labeled "left pelvic lymph node." The specimen consists of multiple yellow/tan fibroadipose tissue fragments with an aggregate measurement of 4.5 x 3.0 x 1.2 cm. Six lymph node candidates are identified within ranging between 0.7 up to 2.5 cm in diameter.

Block Summary:

- E1 - three lymph node candidates
- E2 - two lymph node candidates
- E3 - one lymph node candidate, bisected
- E4 - remaining fibroadipose tissue,

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the manufacturer. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Signature

Resident Physician:

Attending Pathologist:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 37bceb33-4bd3-4148-a44a-7ae4d141d308 (TCGA-EY-A1G8.2454950F-8B3D-4690-98CA-B94C79F99552.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).